Somatic mutation profile of tumor specimen C3N-01408-02 (aliquot CPT0117850009) from CPTAC case C3N-01408, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 58.3 years (21,281 days).
Specimen C3N-01408-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c418a469-d37a-4ac1-b2a2-7a16260dfc7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01408-31 (Blood Derived Normal), aliquot CPT0119090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46040cf5-4b16-444d-a3c5-3a5cb8b94ec6

The open-access MAF lists 344 somatic variants for this specimen: 238 protein-altering or splice-affecting, 65 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 194, Silent 65, Nonsense Mutation 20, Intron 20, Splice Site 11, RNA 11, Frame Shift Del 7, 5'UTR 6, Frame Shift Ins 3, Splice Region 2, 3'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 28/236 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706780, COSV66707774; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 1096/1488 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.994-1G>A p.X332_splice | Splice Site (SNP) | VAF 45/316 reads (14%) | hotspot (GDC flag); catalogued as rs587782272, CS002470, CS033842, CS103209, COSV52668116, COSV52746625, COSV52766192; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.707A>C p.Y236S | Missense Mutation (SNP) | VAF 54/314 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA7 | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 19/132 reads (14%) | catalogued as rs771935858; called by muse, mutect2, varscan2
- ABCA9 | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.089); catalogued as rs1225266364, COSV100382968, COSV60621720; called by muse, mutect2, varscan2
- ADGRB3 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.953); catalogued as COSV65402105; called by muse, mutect2, varscan2
- ADGRL3 | c.1940C>A p.T647K (on ENST00000506720 / NM_001322402.2; = p.T579K on NM_015236.6) | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as COSV63368425; called by muse, mutect2, varscan2
- AP002512.3 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV54406614; called by muse, mutect2
- AP1M2 | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51568131; called by muse, mutect2, varscan2
- ATP6V1G3 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.258); catalogued as rs774551191; called by muse, mutect2, varscan2
- ATXN1 | c.1924G>A p.V642I | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as rs759634141; called by muse, mutect2, varscan2
- BTAF1 | c.4375C>T p.R1459C | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56436355; called by muse, mutect2, varscan2
- CCDC197 | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV58940187; called by muse, mutect2, varscan2
- CDC14A | c.1406G>A p.G469D | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs780042010; called by muse, mutect2, varscan2
- CDH20 | c.192C>A p.N64K | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs780787802; called by muse, mutect2, varscan2
- CFC1 | c.204G>T p.W68C | Missense Mutation (SNP) | VAF 55/509 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs371700198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD7 | c.8623G>T p.G2875C | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as COSV71113823; called by muse, mutect2, varscan2
- CHRM2 | c.509C>A p.T170N | Missense Mutation (SNP) | VAF 61/350 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV57775645; called by muse, mutect2, varscan2
- CLDN17 | c.580G>T p.G194W | Missense Mutation (SNP) | VAF 64/374 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54523592; called by muse, mutect2, varscan2
- CNTN1 | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs148624625, COSV61641574; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL2A1 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61532034; called by muse, mutect2, varscan2
- CTNNA2 | c.1843C>A p.L615M | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.807); catalogued as COSV58133816; called by muse, mutect2, varscan2
- DIO2 | c.325G>T p.G109* | Nonsense Mutation (SNP) | VAF 26/214 reads (12%) | catalogued as COSV70444888, COSV70445282; called by muse, mutect2, varscan2
- DUOX1 | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 27/140 reads (19%) | catalogued as rs1171654246; called by muse, mutect2, varscan2
- FAM227A | c.827A>T p.N276I | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1211506702; called by muse, mutect2, varscan2
- FAT3 | c.11480G>T p.G3827V | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53193861; called by muse, mutect2, varscan2
- FBXO39 | c.338G>C p.R113P | Missense Mutation (SNP) | VAF 67/365 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.381); catalogued as COSV58622840; called by muse, mutect2, varscan2
- FMN2 | c.2896C>A p.L966I | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.018); catalogued as COSV60451239, COSV60451256; called by muse, varscan2
- FMO3 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs971262668; called by muse, mutect2, varscan2
- GABRA2 | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62919553; called by muse, mutect2
- GATA2 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.3); catalogued as rs753645971, COSV62003528, COSV62006283; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GPBP1L1 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as COSV51968040; called by muse, mutect2, varscan2
- H2AZ1 | c.127A>C p.S43R | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV56455490; called by muse, mutect2, varscan2
- HS3ST4 | c.881C>A p.A294D | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100500472; called by muse, mutect2, varscan2
- IMP3 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs1283705591; called by muse, mutect2, varscan2
- INHBA | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 40/308 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as COSV54224127; called by muse, mutect2, varscan2
- IREB2 | c.1865G>T p.R622L | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51921758; called by muse, mutect2, varscan2
- JUNB | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.405); catalogued as rs761390844; called by muse, mutect2, varscan2
- KCNA1 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.097); catalogued as rs1430294104, COSV66837880; called by muse, mutect2, varscan2
- KRT73 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs763594071; called by muse, mutect2, varscan2
- LAMB1 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs371384158; called by muse, mutect2
- LCE2B | c.244C>A p.H82N | Missense Mutation (SNP) | VAF 77/284 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.1); catalogued as COSV100909357; called by muse, mutect2, varscan2
- LENG8 | c.2232G>T p.M744I | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.076); catalogued as COSV58726304; called by muse, mutect2, varscan2
- MAB21L3 | c.1039G>T p.A347S | Missense Mutation (SNP) | VAF 71/361 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV65674104; called by muse, mutect2, varscan2
- MED13L | c.3509G>T p.R1170L | Missense Mutation (SNP) | VAF 106/555 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV104442044; called by muse, mutect2, varscan2
- MUC12 | c.3529C>A p.P1177T (on ENST00000379442; = p.P1034T on NM_001164462.1) | Missense Mutation (SNP) | VAF 68/706 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs894483480; called by muse, mutect2, varscan2
- MUC12 | c.3530C>A p.P1177H (on ENST00000379442; = p.P1034H on NM_001164462.1) | Missense Mutation (SNP) | VAF 56/263 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1452858339; called by mutect2, varscan2
- NDNF | c.1644A>G p.I548M | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV65632635; called by muse, mutect2, varscan2
- NFASC | c.1304C>A p.P435H (on ENST00000339876 / NM_001378329.1; = p.P446H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100363457; called by muse, mutect2, varscan2
- NLRP2 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54753356; called by muse, mutect2, varscan2
- NTRK2 | c.2232G>T p.W744C (on ENST00000323115 / NM_001369534.1; = p.W760C on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99451688; called by muse, mutect2, varscan2
- OR10K2 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 142/467 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100149447, COSV59220398; called by muse, mutect2, varscan2
- OR11G2 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100639897, COSV100639919; called by muse, mutect2, varscan2
- OR2AK2 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV63562544; called by muse, mutect2, varscan2
- OR2M2 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 135/630 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1420643375; called by muse, mutect2, varscan2
- OR5AS1 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 49/380 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1351853859, COSV100546288, COSV57982204; called by muse, mutect2, varscan2
- OR7G2 | c.600T>A p.C200* | Nonsense Mutation (SNP) | VAF 53/365 reads (15%) | catalogued as COSV59688920; called by muse, mutect2, varscan2
- PCDHGA3 | c.685C>A p.Q229K | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs779305386, COSV54049793; called by muse, mutect2, varscan2
- PKP2 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.069); catalogued as rs149542398, CM1511405; called by muse, mutect2, varscan2
- PLAUR | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as rs992988583; called by muse, mutect2, varscan2
- PNLIP | c.103G>T p.G35* | Nonsense Mutation (SNP) | VAF 38/307 reads (12%) | catalogued as COSV100981803; called by muse, mutect2, varscan2
- PNP | c.246G>T p.Q82H | Missense Mutation (SNP) | VAF 51/312 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs779297442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRODH2 | c.449C>A p.A150E (on ENST00000301175; = p.A74E on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.444); catalogued as COSV56562366; called by muse, mutect2, varscan2
- PRSS41 | c.224T>A p.V75E | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs1308961626; called by muse, mutect2, varscan2
- RAPGEF6 | c.3965A>G p.H1322R | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.031); catalogued as rs549318728; called by muse, mutect2, varscan2
- RBM10 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 42/199 reads (21%) | catalogued as COSV100237770, COSV61308772, COSV61309636; called by muse, mutect2, varscan2
- SETD2 | c.5918C>T p.P1973L | Missense Mutation (SNP) | VAF 61/302 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV100338975; called by muse, mutect2, varscan2
- SLC2A7 | c.1122G>T p.R374S | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as rs752931488; called by muse, mutect2, varscan2
- SMG5 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV62433880; called by muse, mutect2, varscan2
- SSH2 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs184610184; called by muse, mutect2
- ST8SIA4 | c.684C>A p.F228L | Missense Mutation (SNP) | VAF 76/410 reads (19%) | PolyPhen benign (0.115); catalogued as COSV99185279; called by muse, mutect2, varscan2
- SV2A | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 42/510 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100975267; called by muse, mutect2
- TBX3 | c.1492C>A p.L498M (on ENST00000257566 / NM_016569.4; = p.L478M on NM_005996.4) | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV57476896; called by muse, mutect2, varscan2
- TCF20 | c.1695G>C p.Q565H | Missense Mutation (SNP) | VAF 37/368 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV59488213; called by muse, mutect2, varscan2
- TRIM9 | c.335A>T p.H112L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV53626419; called by muse, varscan2
- TRPM2 | c.2906G>T p.G969V | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55970480; called by muse, mutect2, varscan2
- VCAN | c.5809G>T p.D1937Y | Missense Mutation (SNP) | VAF 68/412 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54111792; called by muse, mutect2, varscan2
- VWC2 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61483836, COSV61485442; called by muse, varscan2
- XIRP2 | c.5678C>A p.T1893N (on ENST00000628543; = p.T2068N on NM_152381.6) | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54736230; called by muse, mutect2, varscan2
- ZNF536 | c.1563C>A p.Y521* | Nonsense Mutation (SNP) | VAF 45/260 reads (17%) | catalogued as COSV62818454; called by muse, mutect2, varscan2
- ABCD2 | c.686C>G p.T229S | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ABRAXAS2 | c.220A>T p.K74* | Nonsense Mutation (SNP) | VAF 21/196 reads (11%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.1257G>T p.M419I | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRL1 | c.758A>G p.N253S (on ENST00000340736 / NM_001008701.3; = p.N248S on NM_014921.5) | Missense Mutation (SNP) | VAF 41/274 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AGK | c.376G>T p.G126W | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHI1 | c.2176A>C p.K726Q | Missense Mutation (SNP) | VAF 59/373 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ANKRD26 | c.4999+2T>G p.X1667_splice | Splice Site (SNP) | VAF 29/222 reads (13%) | called by muse, mutect2, varscan2
- ANLN | c.968G>A p.S323N | Missense Mutation (SNP) | VAF 130/435 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- APOBR | c.3158G>T p.G1053V (on ENST00000431282; = p.G1062V on NM_018690.4) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- APOOL | c.514A>T p.S172C | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ARAP3 | c.479A>T p.Y160F | Missense Mutation (SNP) | VAF 37/292 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- ARMC9 | c.1354A>G p.M452V | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATP4A | c.1042C>A p.L348M | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BIRC6 | c.10780G>A p.D3594N | Missense Mutation (SNP) | VAF 29/374 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- C10orf71 | c.4279G>T p.E1427* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- C10orf90 | c.300T>G p.F100L | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, varscan2
- C19orf84 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 78/335 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- C9orf131 | c.56G>A p.W19* | Nonsense Mutation (SNP) | VAF 46/305 reads (15%) | called by muse, mutect2, varscan2
- CCL3L3 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 92/1953 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.14); called by muse, mutect2
- CDC27 | c.1408G>T p.G470W | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDH15 | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 63/397 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CDHR1 | c.2498G>A p.G833E | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK18 | c.254A>C p.Q85P | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.596); called by muse, mutect2
- CFAP20DC | c.1749G>T p.Q583H | Missense Mutation (SNP) | VAF 75/338 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CIDEA | c.177C>G p.I59M | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); called by muse, varscan2
- CRAT | c.882G>T p.R294S | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CREB3L4 | c.543G>T p.L181= | Splice Region (SNP) | VAF 62/177 reads (35%) | called by muse, mutect2, varscan2
- CYP26C1 | c.430-2A>T p.X144_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- DBF4 | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- DCLRE1A | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- DDX41 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DGKG | c.1936G>T p.D646Y | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DLGAP1 | c.501G>C p.K167N | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2
- DNAH14 | c.4518dup p.R1507Sfs*7 (on ENST00000445597; = p.R1912Sfs*7 on NM_001367479.1) | Frame Shift Ins (INS) | VAF 57/307 reads (19%) | called by mutect2, pindel, varscan2
- DOCK1 | c.4284T>A p.F1428L | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- DPY19L2 | c.1590_1591del p.L531* | Frame Shift Del (DEL) | VAF 30/197 reads (15%) | called by mutect2, pindel, varscan2
- DSCAM | c.2779+1G>T p.X927_splice | Splice Site (SNP) | VAF 10/135 reads (7%) | called by muse, mutect2
- DSP | c.1099T>A p.C367S | Missense Mutation (SNP) | VAF 90/561 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EEF1AKNMT | c.536G>T p.W179L (on ENST00000361735 / NM_015935.5; = p.W93L on NM_014955.3) | Missense Mutation (SNP) | VAF 98/310 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ELAC1 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ELF4 | c.1120A>T p.I374F | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EYS | c.1952C>A p.S651Y | Missense Mutation (SNP) | VAF 68/456 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FANCF | c.938G>A p.S313N | Missense Mutation (SNP) | VAF 140/657 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FBN2 | c.657G>T p.Q219H | Missense Mutation (SNP) | VAF 106/557 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- FBXO24 | c.582C>A p.D194E (on ENST00000241071 / NM_033506.3; = p.D232E on NM_012172.5) | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- FERMT2 | c.133A>T p.M45L | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- GHR | c.137-2A>T p.X46_splice | Splice Site (SNP) | VAF 90/541 reads (17%) | called by muse, mutect2, varscan2
- GLIPR2 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- GLRB | c.1298C>G p.S433C | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GON4L | c.1139A>C p.E380A | Missense Mutation (SNP) | VAF 54/521 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- GPA33 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 81/277 reads (29%) | called by muse, mutect2, varscan2
- GPR150 | c.786C>A p.H262Q | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRK4 | c.1274T>G p.L425R (on ENST00000398052 / NM_182982.3; = p.L393R on NM_005307.3) | Missense Mutation (SNP) | VAF 15/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HGF | c.959T>C p.I320T | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HMCN1 | c.15592G>C p.E5198Q | Missense Mutation (SNP) | VAF 90/408 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- HMOX1 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 71/293 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- HOXB7 | c.102T>A p.F34L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- HOXD1 | c.156_158del p.C53del | In Frame Del (DEL) | VAF 23/155 reads (15%) | called by mutect2, pindel, varscan2
- HRNR | c.8045_8070del p.G2682Vfs*8 | Frame Shift Del (DEL) | VAF 55/149 reads (37%) | called by mutect2, pindel
- HSH2D | c.718dup p.T240Nfs*62 | Frame Shift Ins (INS) | VAF 61/277 reads (22%) | called by mutect2, pindel, varscan2
- ITGB3 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 69/401 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- JAK3 | c.1480C>A p.P494T | Missense Mutation (SNP) | VAF 90/527 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- JMY | c.620del p.A207Gfs*42 | Frame Shift Del (DEL) | VAF 20/147 reads (14%) | called by mutect2, pindel, varscan2
- KANSL1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 16/363 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- KCNH4 | c.2879C>A p.A960D | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- KCNQ2 | c.810G>T p.W270C | Missense Mutation (SNP) | VAF 103/604 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KCNQ2 | c.809G>T p.W270L | Missense Mutation (SNP) | VAF 103/616 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KCNT2 | c.2099A>G p.D700G | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIAA0895 | c.641T>C p.L214P (on ENST00000297063 / NM_001100425.2; = p.L163P on NM_015314.3) | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF3B | c.224A>C p.E75A | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- KLHL41 | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); called by muse, mutect2
- KMT2C | c.4942A>G p.M1648V | Missense Mutation (SNP) | VAF 34/389 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- LACTB | c.916A>T p.R306* | Nonsense Mutation (SNP) | VAF 24/152 reads (16%) | called by muse, mutect2
- LARS1 | c.2076G>T p.M692I (on ENST00000394434 / NM_020117.11; = p.M665I on NM_016460.3) | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LCT | c.5044C>T p.H1682Y | Missense Mutation (SNP) | VAF 108/579 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LRIT1 | c.1631C>A p.T544K | Missense Mutation (SNP) | VAF 53/355 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRRC26 | c.346T>C p.W116R | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- LRRIQ1 | c.4327G>T p.E1443* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2
- MAP7 | c.585dup p.S196* | Frame Shift Ins (INS) | VAF 42/235 reads (18%) | called by mutect2, pindel, varscan2
- MAPKBP1 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MATK | c.1284+2T>A p.X428_splice (on ENST00000310132 / NM_139355.3; = p.X429_splice on NM_002378.4) | Splice Site (SNP) | VAF 39/220 reads (18%) | called by muse, mutect2, varscan2
- MBNL1 | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- METAP2 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MRPS28 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 25/227 reads (11%) | called by muse, mutect2, varscan2
- MSH4 | c.1371-1G>T p.X457_splice | Splice Site (SNP) | VAF 33/165 reads (20%) | called by muse, mutect2, varscan2
- MYCT1 | c.28T>C p.C10R | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO1G | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, mutect2
- NAALADL2 | c.637C>A p.Q213K | Missense Mutation (SNP) | VAF 55/297 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- NDUFA6 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 28/751 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); called by muse, mutect2
- NEB | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS1 | c.4255G>A p.A1419T | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- NRG3 | c.1171del p.Q391Kfs*6 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | called by mutect2, pindel, varscan2
- NT5C1B | c.761C>A p.P254H (on ENST00000359846 / NM_001199086.2; = p.P194H on NM_033253.4) | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- NUCB2 | c.671del p.X224_splice | Splice Site (DEL) | VAF 19/138 reads (14%) | called by mutect2, pindel, varscan2
- OR11G2 | c.337A>T p.T113S | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OR2M4 | c.523C>G p.H175D | Missense Mutation (SNP) | VAF 51/327 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2T6 | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- OR5D16 | c.66C>A p.Y22* | Nonsense Mutation (SNP) | VAF 51/217 reads (24%) | called by muse, mutect2, varscan2
- OR6C76 | c.768T>A p.Y256* | Nonsense Mutation (SNP) | VAF 34/161 reads (21%) | called by muse, mutect2, varscan2
- OTUD3 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- OVCH1 | c.1888G>T p.A630S | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- PAX1 | c.1022A>G p.E341G | Missense Mutation (SNP) | VAF 164/573 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- PBX1 | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- PCARE | c.3638C>G p.T1213S | Missense Mutation (SNP) | VAF 55/374 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCDHB12 | c.402G>T p.L134F | Missense Mutation (SNP) | VAF 48/346 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- PIWIL1 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PLK3 | c.765C>A p.C255* | Nonsense Mutation (SNP) | VAF 52/269 reads (19%) | called by muse, mutect2, varscan2
- PMPCB | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PROM1 | c.2513+1G>T p.X838_splice | Splice Site (SNP) | VAF 35/188 reads (19%) | called by muse, mutect2, varscan2
- PTPRN | c.615G>T p.L205F | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RCC1 | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RCOR2 | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 80/277 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RIN3 | c.367+1G>T p.X123_splice | Splice Site (SNP) | VAF 27/129 reads (21%) | called by muse, varscan2
- RIOK1 | c.1703A>G p.K568R | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RPA2 | c.767A>T p.Y256F | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- SAFB | c.1661A>G p.K554R | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SAP130 | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); called by muse, varscan2
- SIPA1L2 | c.1266G>T p.R422S | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SLC14A2 | c.2686C>A p.R896S | Missense Mutation (SNP) | VAF 74/403 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SLC17A2 | c.818T>A p.L273Q | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SLC6A17 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- SMARCC2 | c.17del p.K6Rfs*7 | Frame Shift Del (DEL) | VAF 9/95 reads (9%) | called by mutect2, pindel
- SOX3 | c.257A>T p.N86I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2
- SPATA12 | c.223del p.D75Mfs*25 | Frame Shift Del (DEL) | VAF 50/208 reads (24%) | called by mutect2, pindel, varscan2
- SPP2 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 30/221 reads (14%) | called by muse, mutect2, varscan2
- SPSB1 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- STX1B | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TARBP1 | c.3427A>G p.I1143V | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBX4 | c.1070C>A p.A357D | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TCP1 | c.378-1G>A p.X126_splice | Splice Site (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- TDRD1 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2
- TEX45 | c.643C>A p.Q215K | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- TMC5 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 57/280 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM92 | c.72T>C p.I24= | Splice Region (SNP) | VAF 41/258 reads (16%) | called by muse, mutect2, varscan2
- TMUB1 | c.458C>G p.T153S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); called by mutect2, varscan2
- TNKS1BP1 | c.3779G>T p.W1260L | Missense Mutation (SNP) | VAF 73/295 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TRAV17 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRIM58 | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TSC22D2 | c.83A>T p.E28V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, varscan2
- TSPAN2 | c.210G>T p.M70I | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.412); called by muse, varscan2
- TTLL10 | c.410T>A p.L137H (on ENST00000379289 / NM_001130045.2; = p.L64H on NM_153254.3) | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- TTN | c.70771G>C p.D23591H (on ENST00000591111; = p.D16167H on NM_003319.4) | Missense Mutation (SNP) | VAF 31/299 reads (10%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUBGCP3 | c.2233G>T p.D745Y | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBA6 | c.1399G>A p.G467R | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UCMA | c.279A>T p.Q93H | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- UNC45B | c.1650G>T p.Q550H | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UNC79 | c.3709T>C p.S1237P (on ENST00000393151 / NM_001346218.2; = p.S1060P on NM_020818.5) | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- USP30 | c.990G>T p.W330C | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VANGL2 | c.1315del p.E439Sfs*25 | Frame Shift Del (DEL) | VAF 121/474 reads (26%) | called by mutect2, pindel, varscan2
- VCAM1 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ZC3H6 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, varscan2
- ZMYM1 | c.768T>G p.H256Q | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF354C | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF568 | c.1507G>T p.G503C | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF714 | c.1162A>T p.K388* | Nonsense Mutation (SNP) | VAF 58/355 reads (16%) | called by muse, mutect2, varscan2
- ZNF8 | c.1588G>T p.A530S | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF98 | c.85T>A p.C29S | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ACSM2B | c.946C>A p.R316= | Silent (SNP) | VAF 52/289 reads (18%) | called by muse, mutect2, varscan2
- ADGRL4 | c.33C>T p.S11= | Silent (SNP) | VAF 19/128 reads (15%) | catalogued as rs1480498804, COSV66061384, COSV66062028; called by muse, mutect2, varscan2
- ANKRD36C | c.303T>A p.P101= | Silent (SNP) | VAF 46/321 reads (14%) | called by muse, mutect2, varscan2
- ASB13 | c.211C>T p.L71= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs925845641; called by muse, mutect2, varscan2
- BCO2 | c.789G>A p.E263= | Silent (SNP) | VAF 28/174 reads (16%) | catalogued as rs1367588714; called by muse, mutect2, varscan2
- BNC2 | c.1323G>T p.V441= | Silent (SNP) | VAF 78/370 reads (21%) | called by muse, mutect2, varscan2
- BOD1L1 | c.8700C>T p.V2900= | Silent (SNP) | VAF 31/200 reads (16%) | catalogued as rs1416522112; called by muse, mutect2, varscan2
- C11orf68 | c.471G>A p.V157= (on ENST00000530188; = p.V198= on NM_031450.4) | Silent (SNP) | VAF 53/239 reads (22%) | catalogued as rs1477897586; called by muse, mutect2, varscan2
- CACNA1A | c.3669C>A p.P1223= | Silent (SNP) | VAF 54/317 reads (17%) | called by muse, mutect2, varscan2
- CDH20 | c.1860C>T p.G620= | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as rs766055173, COSV53016203; called by muse, mutect2, varscan2
- CERS4 | c.75A>G p.L25= | Silent (SNP) | VAF 26/157 reads (17%) | catalogued as COSV99250874; called by muse, mutect2, varscan2
- CFH | c.1485G>C p.G495= | Silent (SNP) | VAF 27/426 reads (6%) | catalogued as COSV66409223; called by muse, mutect2
- CHD5 | c.4788A>T p.P1596= | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- CHRM5 | c.147C>A p.V49= | Silent (SNP) | VAF 64/352 reads (18%) | called by muse, mutect2, varscan2
- COL11A1 | c.4275A>C p.A1425= | Silent (SNP) | VAF 39/226 reads (17%) | called by muse, mutect2, varscan2
- CPZ | c.1182G>A p.K394= (on ENST00000360986 / NM_001014447.3; = p.K383= on NM_003652.3) | Silent (SNP) | VAF 18/193 reads (9%) | called by muse, mutect2, varscan2
- CUEDC1 | c.882C>G p.A294= | Silent (SNP) | VAF 41/285 reads (14%) | catalogued as COSV100804655; called by muse, mutect2, varscan2
- DCAF12 | c.1284G>T p.S428= | Silent (SNP) | VAF 34/195 reads (17%) | catalogued as COSV63512613; called by muse, mutect2, varscan2
- DSC2 | c.2217A>G p.V739= | Silent (SNP) | VAF 87/395 reads (22%) | catalogued as rs956665667; called by muse, mutect2, varscan2
- EBF4 | c.420C>A p.I140= (on ENST00000609451; = p.I136= on NM_001110514.1) | Silent (SNP) | VAF 32/86 reads (37%) | called by muse, mutect2, varscan2
- EFCAB5 | c.501A>C p.T167= | Silent (SNP) | VAF 55/334 reads (16%) | called by muse, mutect2, varscan2
- EPC1 | c.729A>T p.R243= | Silent (SNP) | VAF 43/268 reads (16%) | called by muse, mutect2, varscan2
- FAM135B | c.2457T>A p.S819= | Silent (SNP) | VAF 19/193 reads (10%) | called by muse, mutect2
- FOCAD | c.2883G>T p.L961= | Silent (SNP) | VAF 32/136 reads (24%) | called by muse, varscan2
- FZD10 | c.465G>A p.S155= | Silent (SNP) | VAF 33/179 reads (18%) | catalogued as rs1324470180, COSV57472461; called by muse, mutect2, varscan2
- GRM4 | c.2475G>T p.S825= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as COSV100946835; called by muse, mutect2, varscan2
- GSE1 | c.3516G>T p.V1172= | Silent (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
- HEXD | c.126C>T p.L42= | Silent (SNP) | VAF 38/296 reads (13%) | catalogued as rs758271479, COSV60066247; called by muse, mutect2, varscan2
- IQCE | c.1500G>A p.P500= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as rs202237035; called by muse, mutect2, varscan2
- KCNH4 | c.2880C>A p.A960= | Silent (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- KLC4 | c.423G>A p.E141= | Silent (SNP) | VAF 25/177 reads (14%) | called by muse, mutect2, varscan2
- KLHL34 | c.195C>A p.S65= | Silent (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- KRT38 | c.1053C>A p.A351= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as COSV55845324; called by muse, mutect2, varscan2
- LRRIQ1 | c.225G>C p.L75= | Silent (SNP) | VAF 27/147 reads (18%) | called by muse, mutect2, varscan2
- MAL | c.327C>A p.A109= | Silent (SNP) | VAF 46/312 reads (15%) | called by muse, mutect2, varscan2
- MAML2 | c.1176C>T p.S392= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV73263210; called by muse, mutect2, varscan2
- MMACHC | c.549A>T p.V183= | Silent (SNP) | VAF 65/318 reads (20%) | called by muse, mutect2, varscan2
- MRC1 | c.2595G>A p.L865= | Silent (SNP) | VAF 28/382 reads (7%) | called by muse, mutect2
- MUC16 | c.16461T>A p.P5487= | Silent (SNP) | VAF 71/386 reads (18%) | called by muse, mutect2, varscan2
- MUC17 | c.9318A>G p.P3106= | Silent (SNP) | VAF 41/162 reads (25%) | called by muse, mutect2, varscan2
- MYADML2 | c.270C>G p.A90= | Silent (SNP) | VAF 31/196 reads (16%) | called by muse, mutect2, varscan2
- MYLK | c.864G>T p.L288= | Silent (SNP) | VAF 17/78 reads (22%) | called by muse, varscan2
- NLRP11 | c.1137A>G p.T379= | Silent (SNP) | VAF 30/215 reads (14%) | called by muse, mutect2, varscan2
- PAPPA | c.3165G>A p.V1055= | Silent (SNP) | VAF 42/168 reads (25%) | catalogued as COSV100073682; called by muse, mutect2, varscan2
- PCDHB11 | c.1314T>A p.T438= | Silent (SNP) | VAF 94/488 reads (19%) | catalogued as rs201085249; called by muse, mutect2, varscan2
- PCDHGA3 | c.684C>A p.I228= | Silent (SNP) | VAF 36/238 reads (15%) | catalogued as COSV53989590; called by muse, mutect2, varscan2
- PCDHGB6 | c.1719G>T p.A573= | Silent (SNP) | VAF 66/373 reads (18%) | catalogued as rs767370997; called by muse, mutect2, varscan2
- PDHA1 | c.135G>T p.R45= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV63329340; called by muse, mutect2, varscan2
- PLCL1 | c.714A>T p.T238= | Silent (SNP) | VAF 59/396 reads (15%) | called by muse, mutect2, varscan2
- PRSS35 | c.1017C>T p.C339= | Silent (SNP) | VAF 42/223 reads (19%) | catalogued as rs751722572; called by muse, mutect2, varscan2
- PRSS36 | c.1776G>T p.L592= | Silent (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- RBP3 | c.1272A>C p.A424= | Silent (SNP) | VAF 50/508 reads (10%) | called by muse, mutect2
- RFX8 | c.558G>A p.L186= (on ENST00000646446; = p.L115= on NM_001145664.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 43/251 reads (17%) | called by muse, mutect2, varscan2
- SHLD3 | c.111A>G p.R37= | Silent (SNP) | VAF 38/187 reads (20%) | called by muse, mutect2, varscan2
- SLIT3 | c.3408G>T p.V1136= | Silent (SNP) | VAF 26/148 reads (18%) | called by muse, mutect2, varscan2
- SPEG | c.5485C>A p.R1829= | Silent (SNP) | VAF 25/203 reads (12%) | catalogued as COSV56676440; called by muse, mutect2, varscan2
- STRN | c.273A>G p.Q91= | Silent (SNP) | VAF 30/216 reads (14%) | called by muse, mutect2, varscan2
- TAF4B | c.2466A>T p.T822= | Silent (SNP) | VAF 27/157 reads (17%) | called by muse, mutect2, varscan2
- TOR1AIP2 | c.63A>G p.P21= | Silent (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- TRPA1 | c.594A>T p.G198= | Silent (SNP) | VAF 38/251 reads (15%) | called by muse, mutect2, varscan2
- TTC13 | c.1539G>C p.L513= | Silent (SNP) | VAF 17/301 reads (6%) | catalogued as COSV64170326; called by muse, mutect2
- TTLL8 | c.613C>T p.L205= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as rs1208031008; called by muse, mutect2, varscan2
- UNC5D | c.1200C>T p.V400= | Silent (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2
- WFIKKN2 | c.1167C>T p.P389= | Silent (SNP) | VAF 45/255 reads (18%) | catalogued as rs562821465, COSV60957999; called by muse, mutect2, varscan2
- ZNF425 | c.1125C>A p.T375= | Silent (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- AC005400.1 | n.179-4748A>G | Intron (SNP) | VAF 23/157 reads (15%) | catalogued as rs559612297; called by muse, mutect2, varscan2
- ANAPC5 | c.207+1040C>T | Intron (SNP) | VAF 18/128 reads (14%) | catalogued as rs530573503; called by muse, mutect2, varscan2
- ARNT | c.-23C>T | 5'UTR (SNP) | VAF 38/198 reads (19%) | called by muse, mutect2, varscan2
- ARNT2 | c.-51G>A | 5'UTR (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- BHLHE22 | chr8:64576308 T>C | 5'Flank (SNP) | VAF 27/147 reads (18%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1102G>T | RNA (SNP) | VAF 28/186 reads (15%) | called by muse, mutect2, varscan2
- C20orf197 | n.484C>G | RNA (SNP) | VAF 94/392 reads (24%) | called by muse, mutect2, varscan2
- CDH13 | c.45+78046C>A | Intron (SNP) | VAF 35/206 reads (17%) | called by muse, mutect2, varscan2
- CEP128 | c.2959-235G>T | Intron (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- COL11A1 | c.2142+10T>A | Intron (SNP) | VAF 22/306 reads (7%) | catalogued as rs779206095; called by muse, mutect2
- COL1A1 | c.1984-12C>T | Intron (SNP) | VAF 53/284 reads (19%) | catalogued as rs1454332648; called by muse, mutect2, varscan2
- ERCC6 | c.1398-13A>G | Intron (SNP) | VAF 37/307 reads (12%) | called by muse, mutect2, varscan2
- GPRC5C | c.1187-174del | Intron (DEL) | VAF 36/238 reads (15%) | called by mutect2, varscan2
- GVINP1 | n.4819C>A | RNA (SNP) | VAF 55/235 reads (23%) | called by muse, mutect2, varscan2
- HDAC6 | c.2188-11C>T | Intron (SNP) | VAF 286/438 reads (65%) | catalogued as rs781974405; called by muse, varscan2
- HDAC6 | c.2188-10C>T | Intron (SNP) | VAF 280/434 reads (65%) | called by muse, varscan2
- IGFN1 | c.1242-1284G>A | Intron (SNP) | VAF 33/151 reads (22%) | called by muse, mutect2, varscan2
- LINC01548 | n.460G>T | RNA (SNP) | VAF 11/188 reads (6%) | called by muse, mutect2
- OR1D4 | n.99C>A | RNA (SNP) | VAF 77/528 reads (15%) | catalogued as rs775491251; called by muse, mutect2, varscan2
- OR2M1P | n.207G>T | RNA (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2, varscan2
- OR2M1P | n.335G>C | RNA (SNP) | VAF 18/426 reads (4%) | called by muse, mutect2
- PDIA3P1 | n.1567G>A | RNA (SNP) | VAF 71/455 reads (16%) | called by muse, mutect2
- PPP2R2B | c.1052+898C>A | Intron (SNP) | VAF 24/205 reads (12%) | called by muse, mutect2, varscan2
- PTGER3 | c.*24-16448G>A | Intron (SNP) | VAF 20/146 reads (14%) | catalogued as rs1214286276; called by muse, mutect2, varscan2
- REG3A | c.-4C>G | 5'UTR (SNP) | VAF 27/156 reads (17%) | catalogued as COSV59411710; called by muse, mutect2, varscan2
- REXO1L1P | n.30C>A | RNA (SNP) | VAF 37/1598 reads (2%) | called by muse, mutect2
- RHOT2 | c.179-39del | Intron (DEL) | VAF 64/332 reads (19%) | called by mutect2, pindel, varscan2
- RPGR | c.2520+878G>C | Intron (SNP) | VAF 8/37 reads (22%) | called by muse, varscan2
- SATB2 | c.-60+1759T>A | Intron (SNP) | VAF 25/223 reads (11%) | called by muse, mutect2, varscan2
- SELENOI | c.-77A>T | 5'UTR (SNP) | VAF 32/213 reads (15%) | called by muse, mutect2, varscan2
- SLC22A4 | c.824+2178G>T | Intron (SNP) | VAF 39/214 reads (18%) | called by muse, mutect2, varscan2
- SLC4A10 | c.49-62202G>C | Intron (SNP) | VAF 34/212 reads (16%) | catalogued as COSV55792878; called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088122 A>C | 3'Flank (SNP) | VAF 20/254 reads (8%) | called by muse, mutect2
- TEPSIN | c.455-13G>T | Intron (SNP) | VAF 37/101 reads (37%) | called by muse, mutect2, varscan2
- TG | c.6563-61G>T | Intron (SNP) | VAF 24/249 reads (10%) | called by muse, mutect2
- TRIM51BP | n.753A>G | RNA (SNP) | VAF 16/212 reads (8%) | catalogued as rs1371282259; called by muse, mutect2
- TRPM7 | chr15:50552620 A>T | 3'Flank (SNP) | VAF 30/210 reads (14%) | called by muse, mutect2, varscan2
- TUFT1 | c.-9del | 5'UTR (DEL) | VAF 19/169 reads (11%) | catalogued as COSV99642575; called by mutect2, pindel, varscan2
- XIRP2 | c.-51G>C | 5'UTR (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- ZNF252P | n.995A>C | RNA (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- ZRANB2 | c.*10A>G | 3'UTR (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
